Gene-level copy-number profile of tumor specimen TCGA-M7-A722-01A from TCGA case TCGA-M7-A722, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.4 years (23,880 days).
Specimen TCGA-M7-A722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.6a7813dc-59c9-4796-9264-b43536630523.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-M7-A722-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aeeeedf6-918b-478e-8ed1-1ca93380f1d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 4,197; copy number 2: 55,291; copy number 3: 283.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-M7-A722-01A-12D-A363-01): tumor purity 0.88, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:128,768,228–129,975,329, 14 genes: JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2, LINC02466, LINC02465, EEF1GP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,851. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
